Somatic mutation profile of tumor specimen TCGA-CV-A45Y-01A (aliquot TCGA-CV-A45Y-01A-11D-A25D-08) from TCGA case TCGA-CV-A45Y, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 61.4 years (22,442 days).
Specimen TCGA-CV-A45Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88c7e38b-8e11-491c-8733-2d7a885187cb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-A45Y-10A (Blood Derived Normal), aliquot TCGA-CV-A45Y-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79ef1074-16b0-414a-b6db-0e4b28f709dd

The open-access MAF lists 67 somatic variants for this specimen: 51 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 15, Nonsense Mutation 4, Splice Site 1, Frame Shift Del 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.566C>G p.S189* | Nonsense Mutation (SNP) | VAF 3/35 reads (9%) | catalogued as COSV55950238, COSV99788686; called by muse, mutect2
- ACBD3 | c.1429G>C p.D477H | Missense Mutation (SNP) | VAF 5/119 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100830904; called by muse, mutect2
- ADAM18 | c.96G>T p.K32N | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55857027, COSV99695021; called by muse, mutect2, varscan2
- AK9 | c.5101C>A p.P1701T | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV101413939; called by muse, mutect2, varscan2
- BTK | c.548A>G p.K183R | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV100437352; called by muse, mutect2, varscan2
- CAMTA1 | c.2328del p.I777Sfs*57 | Frame Shift Del (DEL) | VAF 35/336 reads (10%) | catalogued as COSV57925044; called by mutect2, pindel, varscan2
- CAPNS1 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 7/133 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as COSV99874485; called by muse, mutect2
- CRB2 | c.1199G>T p.C400F | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100749548; called by muse, mutect2
- CSMD3 | c.7297G>A p.A2433T (on ENST00000297405 / NM_001363185.1; = p.A2329T on NM_052900.3) | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as COSV99827030; called by muse, mutect2, varscan2
- DLC1 | c.521T>A p.L174Q | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.006); catalogued as COSV99361581; called by muse, mutect2
- DNAJC11 | c.631-2A>T p.X211_splice | Splice Site (SNP) | VAF 4/22 reads (18%) | catalogued as COSV99601908; called by muse, mutect2
- DNMT3A | c.449G>T p.G150V | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.972); catalogued as COSV99260049; called by muse, mutect2, varscan2
- DSC1 | c.298C>G p.Q100E | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0.266); catalogued as COSV99937312; called by muse, mutect2
- ERP27 | c.625A>T p.I209L | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.039); catalogued as COSV99844214; called by muse, mutect2, varscan2
- GDPD2 | c.178G>C p.V60L | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV100978560; called by mutect2, varscan2
- GJA5 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs782538185, COSV54783010; called by muse, mutect2, varscan2
- GNL2 | c.2059C>T p.R687* | Nonsense Mutation (SNP) | VAF 6/74 reads (8%) | catalogued as COSV99953497; called by muse, mutect2
- GREM1 | c.148C>G p.P50A | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100277809; called by muse, mutect2, varscan2
- HCN1 | c.1679G>A p.R560H | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV57540284; called by muse, mutect2
- HYOU1 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.953); catalogued as rs1453619560, COSV101345550; called by muse, mutect2, varscan2
- ITPR2 | c.2231G>T p.R744L | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101189851, COSV67265059; called by muse, mutect2, varscan2
- KRT40 | c.821G>C p.R274T | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV66696281; called by muse, mutect2
- LRRC24 | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1436755122, COSV52882917; called by muse, mutect2
- LRRCC1 | c.2803C>G p.L935V | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100835313; called by muse, mutect2
- MARS2 | c.566C>T p.S189L | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV99986512; called by muse, mutect2, varscan2
- MLST8 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs775472115, COSV57029740; called by muse, mutect2
- MROH2B | c.1756A>C p.S586R | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as COSV68182325; called by muse, mutect2, varscan2
- MYH7 | c.4145G>T p.R1382L | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as CM133942, COSV100805760, COSV62517935; called by muse, mutect2, varscan2
- PCDHA5 | c.1240C>T p.R414C | Missense Mutation (SNP) | VAF 10/243 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as rs781993190; called by muse, mutect2
- PREX1 | c.776G>T p.G259V | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100906094; called by muse, mutect2
- RERG | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.186); catalogued as rs764381157, COSV57001710; called by muse, mutect2, varscan2
- RTL5 | c.1026G>C p.E342D | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV101029907; called by muse, mutect2, varscan2
- SERINC5 | c.1102G>C p.E368Q | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.097); catalogued as COSV101549061; called by muse, mutect2
- SIX6 | c.273G>T p.W91C | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100576437, COSV100576453; called by muse, mutect2
- SLC36A1 | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.1); catalogued as COSV99695415; called by muse, mutect2
- SLC6A18 | c.1045G>A p.V349I | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.265); catalogued as rs369530348; called by muse, mutect2, varscan2
- SLFN5 | c.2657T>C p.I886T | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100249542; called by muse, mutect2, varscan2
- SPEN | c.1611C>G p.F537L | Missense Mutation (SNP) | VAF 5/111 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101005033; called by muse, mutect2
- ST8SIA6 | c.919C>G p.L307V | Missense Mutation (SNP) | VAF 13/293 reads (4%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.805); catalogued as COSV101112092; called by muse, mutect2
- TEP1 | c.6601G>A p.A2201T | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as COSV99401790; called by muse, mutect2
- TP53 | c.532dup p.H178Pfs*3 | Frame Shift Ins (INS) | VAF 9/69 reads (13%) | catalogued as COSV99408054; called by mutect2, pindel, varscan2
- TRPC5 | c.2065G>C p.G689R | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.03); catalogued as COSV53286314, COSV99459663; called by muse, mutect2, varscan2
- UGT2B4 | c.299T>C p.L100P | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.629); catalogued as COSV100522240; called by muse, mutect2
- USP53 | c.1384C>T p.Q462* | Nonsense Mutation (SNP) | VAF 11/86 reads (13%) | catalogued as COSV99917553; called by muse, mutect2, varscan2
- VCAN | c.1358C>G p.S453* | Nonsense Mutation (SNP) | VAF 9/89 reads (10%) | catalogued as COSV99424914; called by muse, mutect2, varscan2
- VTA1 | c.574C>G p.Q192E | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100859177; called by muse, mutect2
- ZBBX | c.484C>T p.H162Y | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1056508523, COSV100283251; called by muse, mutect2
- ZFP14 | c.818G>C p.R273P | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.113); catalogued as COSV54201823, COSV54204450, COSV99525040; called by muse, mutect2
- ZFP37 | c.449A>G p.N150S | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as COSV100953201; called by muse, mutect2, varscan2
- ZNF257 | c.372G>C p.K124N | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as COSV101448038; called by muse, mutect2, varscan2
- CD180 | c.78G>C p.Q26H | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.275); called by muse, mutect2
- ADORA2A | c.438C>T p.C146= | Silent (SNP) | VAF 78/303 reads (26%) | catalogued as rs780091269, COSV58378398; called by muse, mutect2, varscan2
- CCDC9B | c.435G>A p.E145= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as rs778068788, COSV101233482; called by muse, mutect2, varscan2
- CLUAP1 | c.1173C>G p.L391= | Silent (SNP) | VAF 5/61 reads (8%) | catalogued as COSV57089539; called by muse, mutect2
- CYP4A22 | c.480G>A p.G160= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV99594649; called by muse, mutect2, varscan2
- FRS3 | c.906G>C p.L302= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV99442656; called by muse, mutect2
- GATA3 | c.1272G>C p.P424= | Silent (SNP) | VAF 11/85 reads (13%) | catalogued as COSV100650848, COSV60517046; called by muse, mutect2, varscan2
- GLOD4 | c.405G>A p.P135= (on ENST00000301328 / NM_001366247.1; = p.P120= on NM_016080.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 7/94 reads (7%) | catalogued as rs1485679528; called by muse, mutect2
- GLS2 | c.1116C>A p.I372= | Silent (SNP) | VAF 6/142 reads (4%) | catalogued as COSV100358220; called by muse, mutect2
- HBD | c.324C>A p.G108= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV53081952; called by muse, mutect2
- NKRF | c.1503T>C p.Y501= | Silent (SNP) | VAF 11/103 reads (11%) | catalogued as COSV100441460; called by muse, mutect2, varscan2
- PRKCD | c.663G>A p.Q221= | Silent (SNP) | VAF 4/60 reads (7%) | catalogued as rs137874318; called by muse, mutect2
- PRPF8 | c.1566C>T p.F522= | Silent (SNP) | VAF 7/143 reads (5%) | catalogued as rs896592476, COSV100517205; called by muse, mutect2
- RP1L1 | c.6420G>A p.E2140= | Silent (SNP) | VAF 22/259 reads (8%) | catalogued as rs760411374, COSV101223006; called by muse, mutect2
- SIAH2 | c.564C>G p.L188= | Silent (SNP) | VAF 14/109 reads (13%) | catalogued as COSV100469141; called by muse, mutect2, varscan2
- SLC8A1 | c.2499T>C p.D833= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV100244887; called by muse, mutect2, varscan2
- BSDC1 | c.-1G>C | 5'UTR (SNP) | VAF 4/68 reads (6%) | catalogued as COSV100344427; called by muse, mutect2
